Somatic mutation profile of tumor specimen 0DD3M5 from CCDI case PBBNEJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.2 years (2,613 days).
Specimen 0DD3M5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) caead965-65b4-459c-ba26-712c039f9b5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DD3MB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdae0eb2-cbb7-4801-9279-cdaf505e7d0c

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNK17 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 35/686 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs142227833, COSV64686024; called by muse, mutect2
- FLNA | c.4881_4882insGAGAT p.P1628Efs*31 (on ENST00000369850 / NM_001110556.2; = p.P1628Efs*38 on NM_001456.3) | Frame Shift Ins (INS) | VAF 79/321 reads (25%) | called by mutect2, varscan2*
- PPM1M | c.521T>C p.V174A (on ENST00000296487; = p.V335A on NM_144641.4) | Missense Mutation (SNP) | VAF 46/297 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RPAP2 | c.1263T>A p.P421= | Silent (SNP) | VAF 16/650 reads (2%) | called by muse, mutect2
